Somatic mutation profile of tumor specimen 0bb9d596-774e-452b-9c89-a6643c (aliquot 0bb9d596-774e-452b-9c89-a6643c_D6_2) from CPTAC case 18BR010, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40.9 years (14,934 days).
Specimen 0bb9d596-774e-452b-9c89-a6643c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99e9421d-8858-48bd-839a-6aebbf1cb1fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen feab8720-9694-4679-917f-f1287c (Blood Derived Normal), aliquot feab8720-9694-4679-917f-f1287c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5589478-5f23-43d9-90a3-2db08983c232

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Intron 1, Splice Site 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CEP89 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201497197; called by muse, mutect2, varscan2
- COQ8A | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs762900727, COSV62023325; ClinVar: uncertain significance; called by muse, mutect2
- IL31RA | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 95/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229853997; called by muse, varscan2
- LY75 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 159/498 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs769682476; called by muse, mutect2, varscan2
- MAP2K4 | c.686-1G>A p.X229_splice | Splice Site (SNP) | VAF 31/71 reads (44%) | catalogued as COSV62257775, COSV62258219, COSV62259799; called by muse, mutect2
- PCDHGB6 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs753193390, COSV99550096; called by muse, mutect2, varscan2
- RHCG | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189423740; called by muse, mutect2, varscan2
- SLITRK2 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | catalogued as COSV59422949, COSV59423046; called by muse, mutect2
- AC021660.3 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SLC35F4 | c.212G>T p.G71V (on ENST00000339762 / NM_001352015.2; = p.S35I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLC7A14 | c.1884G>T p.M628I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- SYT14 | c.224T>A p.I75N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TERF2IP | c.981G>C p.L327F | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- WNK2 | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCPG1 | c.1422C>T p.S474= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- FBLN2 | c.2811C>T p.D937= | Silent (SNP) | VAF 23/277 reads (8%) | catalogued as rs553735734, COSV99851441; called by muse, mutect2
- NOC4L | c.105G>C p.L35= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- NOS3 | c.978G>A p.L326= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- OR1L4 | c.135C>T p.L45= | Silent (SNP) | VAF 32/414 reads (8%) | called by muse, mutect2
- PITPNM1 | c.3027C>T p.A1009= | Silent (SNP) | VAF 54/188 reads (29%) | catalogued as rs762374136; called by muse, mutect2, varscan2
- PNLDC1 | c.1437G>A p.P479= | Silent (SNP) | VAF 12/303 reads (4%) | catalogued as rs1050673094; called by muse, mutect2
- SYT17 | c.16-35C>T | Intron (SNP) | VAF 16/107 reads (15%) | catalogued as rs141792068; called by muse, mutect2, varscan2
- ZNF773 | chr19:57513050 C>T | 3'Flank (SNP) | VAF 10/60 reads (17%) | catalogued as rs769577046; called by muse, mutect2, varscan2
